Surgical pathology report (de-identified scan), TCGA case TCGA-TQ-A7RV, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site University of Sao Paulo, specimen TCGA-TQ-A7RV-02A (Recurrent Tumor).

ICD-0-3

COCE

oligoastrocytoma, 9382/3

path

Astrocytoma, grade II

COCE

Site: Supratentorial brain NOS C71.0

Brain NOS C71.9

9/11/29/14

Nature of material: Brain

Biopsy number:

ANATOMOPATHOLOGIC RESULT

MACROSCOPY

Received 02 identified vials.

Vial 1. Tumor - 06 irregular, soft and grayish-white fragments measuring together 1.8 x 1.3 x 0.7 cm.

Vial 2. Amygdala - nodular, soft and whitish structure, previously sectioned along the longest axis, measuring 0.6 x 0.5 x 0.4 cm.

MICROSCOPY

The histological sections stained with H&E show fragments of neuroepithelial neoplasia composed of cells of convoluted nuclei, sometimes rounded, with dense chromatin and inconspicuous nucleoli. The cytoplasm is scarce, with imprecise limits. Such cells are disposed on fibrillar background, sometimes microvacuolized. Mitotic figures are rare (1 mitosis per 20 contiguous high power fields). Calls attention the the presence of some cells with increased nuclear pleomorphism, forming small clusters of neoplastic cells. The tumor diffusely infiltrates mesial structures in the form of isolated cells, including the amygdala.

DIAGNOSTIC

Resection product of residual malignancy in the insula and mesial portion of the left temporal lobe:

- Diffuse astrocytoma with focal areas of anaplasia, grade II according to the WHO classification (see note).

Note:

- Patient operated in for grade II astrocytoma in the left temporal lobe (see report

PARTICIPANTS OF APPRAISAL REPORT

- ISSUER

Recurrence of primary Grade II astrocytoma.

Criteria	12/12/13	Yes	No
HISPA Discrepancy			
Prior Malignancy History	Grade II astrocytoma		

Source: NCI Genomic Data Commons file cc90ef99-edd9-41d7-874f-3a86201ccf97 (TCGA-TQ-A7RV.98CC2EDE-4503-4D22-8F18-50E97255B658.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).